Somatic mutation profile of tumor specimen HTMCP-03-06-02187-01A (aliquot HTMCP-03-06-02187-01A-01D-6194) from CGCI case HTMCP-03-06-02187, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20502fea-11e0-4527-93e4-550c11c2ca13.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02187-10A (Blood Derived Normal), aliquot HTMCP-03-06-02187-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6b05433-d045-43e3-bf83-c4408c0aa624

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 2, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 122/202 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AOC1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs772488394, COSV62871359; called by muse, mutect2, varscan2
- ARHGAP31 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs747126561, COSV51795044; called by muse, mutect2, varscan2
- ATP7B | c.4187C>T p.T1396M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs528603867, COSV54434713, COSV54434723; called by muse, mutect2, varscan2
- ATP8B4 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs764517232; called by muse, mutect2, varscan2
- CCT5 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs766463234; called by muse, mutect2, varscan2
- CD99L2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as rs143706982, COSV60936782; called by muse, mutect2, varscan2
- COL6A6 | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566520876; called by muse, mutect2, varscan2
- DST | c.1948G>A p.E650K (on ENST00000361203 / NM_001374722.1; = p.E324K on NM_001723.6) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55027382; called by muse, mutect2, varscan2
- EPX | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as rs774499008; called by mutect2, varscan2
- FAM47C | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs375998369, COSV63727370; called by muse, mutect2, varscan2
- FSIP2 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1324442866; called by muse, mutect2, varscan2
- ICE2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs912762907, COSV55030349; called by muse, mutect2, varscan2
- MAP2 | c.5165G>A p.R1722H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.495); catalogued as rs1239778625, COSV52288792; called by muse, mutect2, varscan2
- MYO3B | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs778515727, COSV58692498; called by muse, mutect2, varscan2
- MYT1L | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1385738575, COSV67726359; called by muse, mutect2, varscan2
- NOTCH3 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774985086; called by muse, mutect2, varscan2
- NWD2 | c.4931C>T p.T1644M | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs750496899, COSV58752394; called by muse, mutect2, varscan2
- PAPPA | c.4163G>A p.R1388Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.454); catalogued as rs764379532, COSV60280381; called by muse, mutect2, varscan2
- PCDHGA5 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV53918706; called by muse, mutect2, varscan2
- PHKA1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1556302032; called by muse, mutect2, varscan2
- TDRD1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 39/163 reads (24%) | catalogued as COSV52590484; called by muse, mutect2, varscan2
- TNXB | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1397746200; called by muse, mutect2, varscan2
- WNK3 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV63613436; called by muse, mutect2, varscan2
- ARFGEF3 | c.5645C>A p.A1882E | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ARMC4 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C12orf42 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CERCAM | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CNTN3 | c.1786+2T>A p.X596_splice | Splice Site (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- CNTN3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.8174A>T p.N2725I | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPWD1 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGL4 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RREB1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- SAMD9 | c.1680C>G p.F560L | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ZNF98 | c.1198C>A p.H400N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKAP6 | c.4149C>T p.L1383= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs764558269; called by muse, mutect2, varscan2
- MUC17 | c.5736C>T p.D1912= | Silent (SNP) | VAF 91/408 reads (22%) | catalogued as rs575805315, COSV60288561; called by muse, mutect2, varscan2
- MYH3 | c.1101G>A p.Q367= | Silent (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- NRXN1 | c.1749C>T p.D583= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs199934259, COSV58505412; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.12216C>T p.I4072= (on ENST00000322810 / NM_201380.4; = p.I3962= on NM_000445.5) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs755044609, COSV59605868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP6R3 | c.438G>A p.K146= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- RTL1 | c.1974C>T p.H658= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs1054507893; called by muse, mutect2, varscan2
- SLITRK5 | c.2799G>A p.L933= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- SMG7 | c.1542G>A p.S514= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs141972824; called by muse, mutect2, varscan2
- TRIM71 | c.1383C>T p.F461= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1175231103; called by muse, mutect2, varscan2
- MLLT10P1 | n.181T>A | RNA (SNP) | VAF 50/282 reads (18%) | catalogued as rs73610021; called by muse, varscan2
- TTN | c.63902-9dup | Intron (INS) | VAF 20/86 reads (23%) | called by mutect2, varscan2
